Gene-level copy-number profile of specimen HCM-CSHL-0078-C25-85M from HCMI case HCM-CSHL-0078-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 72.6 years (26,533 days).
Specimen HCM-CSHL-0078-C25-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a78a18ee-4b4d-4efc-b97a-e12d83c89b3a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0078-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/6af0a249-6ca3-4075-8fe9-57774f71085c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,916; copy number 2: 19,567; copy number 3: 22,903; copy number 4: 8,771; copy number 5: 3,298; copy number 6: 96; copy number 7: 418; copy number 8: 224; copy number 9: 30; copy number 10: 106; copy number 11: 47; copy number 12: 24; copy number 13: 105; copy number 14: 148; copy number 15: 36; copy number 16: 104; copy number 17: 1; copy number 21: 8; copy number 23: 95; copy number 24: 16.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,362 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:84,078,062–84,238,498, 1 gene, copy number 9 (within-gene range 2–9): PRKACB.
- chr1:84,244,334–84,397,831, 5 genes, copy number 9: NEDD8P1, AL359273.1, SAMD13, AL359273.2, UOX.
- chr1:87,620,803–88,685,204, 1 gene, copy number 17 (within-gene range 2–17): PKN2-AS1.
- chr1:88,313,153–88,578,201, 5 genes, copy number 10 (within-gene range 10–17): AL049861.1, RN7SL583P, AC093578.1, AC093578.2, RPL36AP10.
- chr1:93,921,268–94,121,148, 10 genes, copy number 9: CHCHD2P5, MTND4P11, MTND3P21, MTCO3P21, MTATP6P13, AL117351.2, MTCO2P21, MTCO1P21, AL117351.1, ABCA4.
- chr1:143,419,625–154,870,281, 495 genes, copy number 7–24 (broad region; genes not listed).
- chr1:155,335,268–155,660,245, 14 genes, copy number 11 (within-gene range 4–11): ASH1L, MIR555, RNU6-106P, ASH1L-IT1, RNU6-1297P, POU5F1P4, ASH1L-AS1, AL353807.4, DAP3P1, AL353807.1, AL353807.2, MSTO1, AL353807.3, AL353807.5.
- chr1:157,573,747–157,598,085, 1 gene, copy number 10: FCRL4.
- chr1:157,674,321–158,186,427, 14 genes, copy number 12: FCRL3, AL356276.1, AL356276.2, VDAC1P9, FCRL2, FCRL1, CD5L, MRPS21P2, AL139010.1, KIRREL1, KIRREL1-IT1, LINC01704, ELL2P1, CD1D.
- chr1:158,254,424–158,357,553, 5 genes, copy number 10: CD1A, HMGN1P5, CD1C, CD1B, CD1E.
- chr1:159,466,321–162,039,567, 128 genes, copy number 10–13 (within-gene range 3–13) (broad region; genes not listed).
- chr1:163,923,670–164,357,364, 4 genes, copy number 14: U3, NMNAT1P2, RNU5F-6P, HMGB3P6.
- chr1:165,400,922–168,075,843, 67 genes, copy number 16 (within-gene range 3–16) (broad region; genes not listed).
- chr1:168,178,962–169,104,907, 26 genes, copy number 9–15: TIPRL, RPL34P1, AL021397.1, SFT2D2, ANKRD36BP1, RNU6-1310P, TBX19, AL022100.1, MIR557, AL023755.1, AL022100.2, QRSL1P1, XCL2, AL031736.1, XCL1, AL031736.2, DPT, AL135926.1, AL031275.1, LINC00626, SUMO1P2, LINC00970, RPL29P7, AL031726.2, RNA5SP66, AL031726.1.
- chr6:25,726,063–28,633,594, 173 genes, copy number 7 (broad region; genes not listed).
- chr6:29,657,002–29,995,314, 38 genes, copy number 7: MOG, ZFP57, ZDHHC20P1, HLA-F, AL645939.1, HLA-F-AS1, RPL23AP1, MICE, AL645939.2, Y_RNA, IFITM4P, AL645939.4, AL645939.5, AL645939.3, HLA-V, HCG4, HLA-P, RPL7AP7, MICG, HLA-G, HCG4P8, AL645929.2, HCP5B, AL645929.1, HLA-H, HLA-T, DDX39BP1, MCCD1P1, HCG4B, HLA-K, HLA-U, HLA-A, AL671277.1, HLA-W, MICD, HCG9, DDX39BP2, MCCD1P2.
- chr6:30,005,971–30,009,956, 2 genes, copy number 7 (within-gene range 4–7): HLA-J, AL671277.2.
- chr6:32,948,613–33,457,544, 48 genes, copy number 7–16 (within-gene range 6–16): HLA-DMA, BRD2, AL645941.1, AL645941.3, HLA-DOA, HLA-DPA1, HLA-DPB1, RPL32P1, HLA-DPA2, COL11A2P1, HLA-DPB2, HLA-DPA3, HCG24, COL11A2, RXRB, RNY4P10, SLC39A7, HSD17B8, MIR219A1, RING1, ZNF70P1, HTATSF1P1, AL645940.1, HCG25, VPS52, RPS18, B3GALT4, WDR46, MIR6873, PFDN6, MIR6834, RGL2, TAPBP, ZBTB22, DAXX, SMIM40, SMIM40, MYL8P, LYPLA2P1, RPL35AP4, KIFC1, RPL12P1, PHF1, CUTA, SYNGAP1, SYNGAP1-AS1, MIR5004, ZBTB9.
- chr6:35,733,867–45,377,953, 252 genes, copy number 7–11 (within-gene range 6–11) (broad region; genes not listed).
- chr6:50,514,035–53,924,125, 72 genes, copy number 8 (within-gene range 4–8) (broad region; genes not listed).
- chr14:18,343,038–18,343,144, 1 gene, copy number 7: RNU6-458P.

Autosomal genes at a single copy (total copy number 1): 60. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
